Surgical pathology report (de-identified scan), TCGA case TCGA-HF-7132, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HF-7132-01A (Primary Tumor).

[page 1 of 4]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details							
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Site of Primary (Event)	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments
	TUMOUR	FF		GAST			
	BUFFY	FF		GAST			

[page 2 of 4]
Histology and staging

Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/ Differentiat ion
------------------------------	----------------------	----------------------	--------------------------------	---------------------	-----------	-------------------------------

RESECT	Antrum of stomach	5	Mucinous adenocarcinoma	II
--------	-------------------	---	-------------------------	----

RESECT	Antrum of stomach	5	Mucinous adenocarcinoma	II
--------	-------------------	---	-------------------------	----

[page 3 of 4]
Pathologic al T	Pathologic al N	Clinical M	Histology	Comments	Slide URL
T2b	N1	M0	Macroscopic tumour configuration: type I (protruded); Borrmann type III (ulcerated tumour with infiltrative margins). h		
T2b	N1	M0	Macroscopic tumour configuration: type I (protruded); Borrmann type III (ulcerated tumour with infiltrative margins).		

Source: NCI Genomic Data Commons file bac75d3a-37d8-47e1-a92c-93e6563829de (TCGA-HF-7132.AF948A18-7E1A-4DA7-979E-5BD2E73B91B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).